Somatic mutation profile of tumor specimen TARGET-30-PAPBJT-01A (aliquot TARGET-30-PAPBJT-01A-01W) from TARGET case TARGET-30-PAPBJT, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 1.6 years (570 days).
Specimen TARGET-30-PAPBJT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf0ba93f-0d87-4cd9-93d4-c33f0e2d4af1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPBJT-10A (Blood Derived Normal), aliquot TARGET-30-PAPBJT-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e0498cc-e5ff-4cda-9e38-8a50a585d765

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR2 | c.1073dup p.A359Cfs*13 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | catalogued as rs312262690; ClinVar: pathogenic; called by pindel, varscan2
